TCGA case TCGA-IE-A6BZ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/885b1b65-4280-4aab-a7f0-434b0317d86f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.5; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of pelvis; Classification of tumor: primary; Age at diagnosis: 65.0 years (23,756 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 19.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 30; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 17; Tumor width measurement: 15.
   Pathology details: Measurement type: Radiologic; Tumor burden: 17.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 8; Tumor length measurement: 19; Tumor width measurement: 11.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Days to follow up: 217 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 605.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IE-A6BZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 230 mg.
  Slide TCGA-IE-A6BZ-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IE-A6BZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IE-A6BZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Discontinuous lesions count: 1; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Superficial Trunk - Buttock.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 8.
- Follow-up form: Lost to follow-up: No.
- Drug treatment 1: Days from index date to pharmaceutical treatment started: 112; Days from index date to pharmaceutical treatment ended: 204; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Days from index date to pharmaceutical treatment started: 112; Days from index date to pharmaceutical treatment ended: 204; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 3: Days from index date to pharmaceutical treatment started: 112; Days from index date to pharmaceutical treatment ended: 204; Pharmaceutical therapy drug name: Mesna; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 3, Therapy types: Pharmaceutical therapy type: Ancillary.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 605 days; disease-specific survival: no event (censored), 605 days; disease-free interval: no event (censored), 605 days; progression-free interval: no event (censored), 605 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IE-A6BZ-01A-11D-A306-01): tumor purity 0.9, ploidy 2.8, whole-genome doublings 1.
